Gene-level copy-number profile of tumor specimen TARGET-10-PATIBE-09A from TARGET case TARGET-10-PATIBE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,106 days).
Specimen TARGET-10-PATIBE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d24d37b1-8fa5-5932-8532-d92086576896.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATIBE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/a44aa6f5-64bd-4d3a-be78-263385e1876f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 584; copy number 1: 22; copy number 2: 56,993; copy number 3: 2,575; copy number 4: 79; copy number 5: 19.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,349,835–26,892,803, 64 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,203,171–49,589,529, 19 genes, copy number 5: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
